Somatic mutation profile of tumor specimen TCGA-CS-6668-01A (aliquot TCGA-CS-6668-01A-11D-1893-08) from TCGA case TCGA-CS-6668, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 57.0 years (20,836 days).
Specimen TCGA-CS-6668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d200dc0e-8d05-4700-8fca-5f8703cf9acc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6668-10A (Blood Derived Normal), aliquot TCGA-CS-6668-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de311832-6695-4442-9d71-494f103d35ef

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ARFGEF2 | c.3616T>C p.C1206R | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213173; called by muse, mutect2, varscan2
- CLIP2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151111065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLX5 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56033249; called by muse, mutect2, varscan2
- ECPAS | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as rs775190017, COSV52200553; called by muse, mutect2, varscan2
- FBXO36 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV52278868; called by muse, mutect2, varscan2
- KRT34 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1254149302, COSV67450082; called by muse, mutect2, varscan2
- LRP1B | c.115T>C p.C39R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67238254; called by muse, mutect2, varscan2
- NT5DC3 | c.1273T>C p.Y425H | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV67322077; called by muse, mutect2, varscan2
- PCDHGA7 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as COSV53972830; called by muse, mutect2, varscan2
- PLCE1 | c.6571G>A p.E2191K | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352634; called by muse, mutect2, varscan2
- PRAMEF1 | c.122T>G p.M41R | Missense Mutation (SNP) | VAF 112/148 reads (76%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs544609656, COSV60011191; called by muse, mutect2, varscan2
- TCP11L2 | c.822A>C p.E274D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.53); catalogued as COSV54430881; called by muse, mutect2, varscan2
- VSIG4 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.748); catalogued as COSV66074095; called by muse, mutect2, varscan2
- CIC | c.2159dup p.S721Lfs*42 | Frame Shift Ins (INS) | VAF 9/17 reads (53%) | called by mutect2, pindel, varscan2
- TCF12 | c.685+2dup p.X229_splice | Splice Site (INS) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.615C>T p.T205= | Silent (SNP) | VAF 112/276 reads (41%) | catalogued as rs376709007, COSV54410946; called by muse, varscan2
- DSG2 | c.600C>T p.I200= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs535646295, COSV55200241; called by muse, mutect2, varscan2
- KCNG2 | c.552G>A p.V184= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV60268607; called by muse, mutect2, varscan2
- MARVELD3 | c.1068C>T p.F356= | Silent (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- PKP1 | c.330G>A p.R110= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV55822520; called by muse, mutect2, varscan2
- POLG | c.2583C>T p.T861= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs372456693; called by muse, mutect2, varscan2
- RNF103 | c.1815A>G p.E605= | Silent (SNP) | VAF 102/272 reads (38%) | catalogued as COSV52895823; called by muse, mutect2, varscan2
